Somatic mutation profile of tumor specimen TCGA-MQ-A6BR-01A (aliquot TCGA-MQ-A6BR-01A-11D-A34C-32) from TCGA case TCGA-MQ-A6BR, project TCGA-MESO (Mesothelioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 55.1 years (20,134 days).
Specimen TCGA-MQ-A6BR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d70e4ee-aef5-4717-a412-fa6b4d016496.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MQ-A6BR-10A (Blood Derived Normal), aliquot TCGA-MQ-A6BR-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1fdf8c4-d2f9-4ed8-815a-81fb4a0c6931

The open-access MAF lists 14 somatic variants for this specimen: 12 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 8, Frame Shift Del 3, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 30/43 reads (70%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ALPK3 | c.4772G>T p.G1591V | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51938567; called by muse, mutect2, varscan2
- BMS1 | c.2068C>G p.R690G | Missense Mutation (SNP) | VAF 55/92 reads (60%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as rs764065209, COSV65735164; called by muse, mutect2, varscan2
- CCDC7 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.89); catalogued as rs1405295728, COSV56550083, COSV56554986; called by muse, mutect2, varscan2
- NF2 | c.258_262del p.S87Gfs*15 | Frame Shift Del (DEL) | VAF 22/48 reads (46%) | catalogued as COSV58528986; called by mutect2, pindel, varscan2
- RANBP2 | c.9379A>G p.I3127V | Missense Mutation (SNP) | VAF 76/118 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); catalogued as COSV51706860; called by muse, mutect2, varscan2
- ROCK1 | c.1967_1968del p.Q656Rfs*4 | Frame Shift Del (DEL) | VAF 17/41 reads (41%) | catalogued as COSV67698720; called by mutect2, pindel, varscan2
- SH2B3 | c.1567G>A p.E523K | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.727); catalogued as rs761330967, COSV57985791; called by muse, mutect2, varscan2
- TRAF6 | c.969G>T p.Q323H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV61923438; called by muse, mutect2, varscan2
- ZMYND8 | c.977A>G p.K326R (on ENST00000311275 / NM_001363741.2; = p.K346R on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV53694863; called by muse, mutect2, varscan2
- LILRB1 | c.303A>T p.K101N (on ENST00000427581; = p.K65N on NM_006669.6) | Missense Mutation (SNP) | VAF 45/204 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.009); called by muse, mutect2
- SETDB1 | c.2021del p.K674Sfs*73 | Frame Shift Del (DEL) | VAF 54/115 reads (47%) | called by mutect2, pindel, varscan2
- CDH6 | c.1149C>T p.F383= | Silent (SNP) | VAF 57/154 reads (37%) | catalogued as COSV54076553; called by muse, mutect2, varscan2
- TOP3A | c.2655C>T p.G885= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as COSV58180473; called by muse, mutect2, varscan2
